Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3680, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3680-01A (Primary Tumor).

Diagnosis:

1. and 2.: Right-sided hemicolectomy preparation with tumor-free oral and aboral resection margins which also includes an ulcerated, moderately differentiated adenocarcinoma of the cecum with invasion of all parietal layers, penetration of the peritoneum, multiple regional lymph node metastases and peritoneal seeding. (G2, pT4 pN2 L1, V0, pN2 12/35 pM1 [REDACTED])

Source: NCI Genomic Data Commons file 6e6a9987-cd3e-4d05-aced-2d9cbd4ef3b8 (TCGA-AA-3680.0CEC2F9E-19B2-4D7F-8ECF-1545393B9A3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).